Somatic mutation profile of tumor specimen TCGA-DM-A1D8-01A (aliquot TCGA-DM-A1D8-01A-11D-A152-10) from TCGA case TCGA-DM-A1D8, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 50.1 years (18,311 days).
Specimen TCGA-DM-A1D8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7655ee5b-81b1-4f49-b53b-824d26df8700.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1D8-10A (Blood Derived Normal), aliquot TCGA-DM-A1D8-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69153507-0ffb-43c1-a1b3-859ae5b9e018

The open-access MAF lists 168 somatic variants for this specimen: 124 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 42, Nonsense Mutation 5, Frame Shift Ins 4, Splice Site 3, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 96/204 reads (47%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 72/154 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 134/274 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 37/46 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS2 | c.2052C>A p.D684E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52364463; called by muse, mutect2, varscan2
- ADGRB3 | c.3371G>A p.R1124H | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs149298585; called by muse, mutect2, varscan2
- ADORA3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV53984934; called by muse, mutect2, varscan2
- AGAP3 | c.2123G>T p.G708V (on ENST00000622464; = p.G744V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV68243192; called by muse, mutect2, varscan2
- AHI1 | c.1034T>G p.L345W | Missense Mutation (SNP) | VAF 95/156 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55622669; called by muse, mutect2, varscan2
- AL592490.1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1472560831, COSV69424444; called by muse, mutect2, varscan2
- AMER1 | c.1230G>A p.W410* | Nonsense Mutation (SNP) | VAF 72/212 reads (34%) | catalogued as COSV57654654; called by muse, mutect2, varscan2
- AMOT | c.2567A>G p.K856R (on ENST00000371959 / NM_001113490.1; = p.K447R on NM_133265.3) | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59060409; called by muse, mutect2, varscan2
- AMY2B | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 54/750 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV100796388; called by muse, mutect2
- ATP8B3 | c.3157G>A p.V1053M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs778738154, COSV59539872; called by muse, mutect2, varscan2
- BANP | c.784C>T p.R262C (on ENST00000286122; = p.R231C on NM_017869.4) | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53733583; called by muse, mutect2, varscan2
- CAND1 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73389521; called by muse, mutect2, varscan2
- CDH18 | c.2030G>T p.R677M | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56900908, COSV56928101; called by muse, mutect2, varscan2
- CELSR3 | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201230994, COSV50891353, COSV51005096; called by muse, mutect2, varscan2
- CFAP52 | c.546T>G p.I182M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); catalogued as COSV100235392; called by muse, mutect2, varscan2
- CLVS1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781486942, COSV57970316; called by muse, mutect2, varscan2
- COL20A1 | c.3170G>T p.C1057F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV58911488; called by muse, mutect2, varscan2
- COL7A1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs778085630, COSV60390567; called by muse, mutect2, varscan2
- CPSF6 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV57012064; called by muse, mutect2, varscan2
- CREM | c.512C>T p.A171V (on ENST00000429130; = p.A138V on NM_181571.3) | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV100415316; called by muse, mutect2
- CTNND2 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.952); catalogued as COSV58864267; called by muse, mutect2, varscan2
- DDX23 | c.1474G>T p.G492W | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339907; called by muse, mutect2, varscan2
- DENND2C | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 146/504 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV67920016, COSV67922793; called by muse, mutect2, varscan2
- DIAPH1 | c.3140C>G p.A1047G | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53878365, COSV53883276; called by muse, mutect2, varscan2
- DIAPH1 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.091); catalogued as COSV53878373; called by muse, varscan2
- EFNB3 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV56832761; called by muse, mutect2, varscan2
- ELMO1 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs762877369, COSV60294903; called by muse, mutect2, varscan2
- EP400 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); catalogued as COSV57762391, COSV57787435; called by muse, mutect2, varscan2
- EPHA5 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 181/321 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56630607; called by muse, mutect2, varscan2
- FAM83H | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101187039; called by muse, mutect2
- FAT4 | c.12848C>T p.T4283I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.731); catalogued as COSV100629300; called by muse, varscan2
- FSTL5 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV60180813, COSV60182834; called by muse, mutect2
- GALNT17 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367824274; called by muse, mutect2, varscan2
- GLIS3 | c.2128T>G p.S710A | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100174426, COSV60923778; called by muse, mutect2, varscan2
- GPR151 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as rs757129065, COSV57033792; called by muse, mutect2, varscan2
- HMG20A | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 79/97 reads (81%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as COSV100287845, COSV60311249; called by muse, mutect2, varscan2
- IGSF9B | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs182679983, COSV58063807; called by muse, mutect2, varscan2
- IL13RA1 | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV65426046; called by muse, mutect2, varscan2
- IL1R2 | c.774T>A p.C258* | Nonsense Mutation (SNP) | VAF 36/140 reads (26%) | catalogued as COSV60205565; called by muse, mutect2, varscan2
- ISM2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.019); catalogued as rs371970567; called by muse, mutect2, varscan2
- ITGA8 | c.1205A>T p.N402I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV65224350; called by muse, mutect2, varscan2
- IVL | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100908206; called by muse, mutect2, varscan2
- KCNC3 | c.1875G>T p.R625S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as rs537912602, COSV65386629; called by muse, mutect2, varscan2
- KCNQ4 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.122); catalogued as rs1200500779, COSV61271954; called by muse, mutect2, varscan2
- KDM3B | c.2345_2346insG p.D782Efs*11 | Frame Shift Ins (INS) | VAF 17/66 reads (26%) | catalogued as COSV58687850; called by pindel, varscan2
- KDM3B | c.2351C>A p.S784* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV58687856; called by muse, varscan2
- LAMA2 | c.4199G>A p.R1400Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs760541670, COSV70338049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs778884818, COSV63088242; called by muse, mutect2, varscan2
- LCE1F | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.942); catalogued as rs372485856; called by muse, mutect2, varscan2
- LIN54 | c.55A>C p.T19P | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV61200041; called by muse, mutect2, varscan2
- LOX | c.1247+1G>A p.X416_splice | Splice Site (SNP) | VAF 45/75 reads (60%) | catalogued as rs1233555524, COSV50236868; called by muse, mutect2, varscan2
- MAMLD1 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV53371930; called by muse, mutect2, varscan2
- MAP7D1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148371637; called by muse, mutect2, varscan2
- MARCHF11 | c.847T>C p.C283R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198099; called by muse, mutect2, varscan2
- MMP24 | c.381T>A p.D127E | Missense Mutation (SNP) | VAF 102/196 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV55768356; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2951G>C p.S984T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56616609; called by muse, mutect2, varscan2
- MRC1 | c.3853C>T p.R1285W | Missense Mutation (SNP) | VAF 476/1142 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); catalogued as rs1279552732; called by muse, mutect2, varscan2
- MYO3A | c.2451C>A p.F817L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99780519; called by muse, mutect2
- NAA20 | c.290A>C p.E97A | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV58548030; called by muse, mutect2, varscan2
- NAALAD2 | c.1732G>T p.V578L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs774232914, COSV58958551; called by muse, mutect2, varscan2
- NELL2 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61568750; called by muse, mutect2
- NHSL2 | c.1997C>T p.P666L (on ENST00000510661; = p.P1032L on NM_001013627.2) | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV65452332; called by muse, mutect2, varscan2
- NKTR | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs747397486, COSV51769260; called by muse, mutect2, varscan2
- NOP53 | c.23T>G p.V8G | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54406655; called by muse, mutect2, varscan2
- NPAP1 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 68/87 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs777875615, COSV100276354, COSV61504334; called by muse, mutect2, varscan2
- NPR3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1020741873, COSV99423474; called by muse, mutect2, varscan2
- NRG1 | c.1205A>C p.N402T (on ENST00000405005 / NM_013964.5; = p.N407T on NM_013956.5) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as COSV55148094; called by muse, mutect2, varscan2
- NSD1 | c.5532G>C p.R1844S | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV61770499; called by muse, mutect2, varscan2
- NTSR1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs148516370; called by muse, mutect2, varscan2
- NYNRIN | c.3390G>T p.W1130C | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66841090; called by muse, mutect2, varscan2
- OAS2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs141277168, COSV60804760; called by muse, mutect2, varscan2
- OFD1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1555900190, COSV60794126; ClinVar: uncertain significance; called by muse, mutect2
- OFD1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV60794150; called by muse, mutect2, varscan2
- OR4C16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58940520; called by muse, mutect2, varscan2
- OR8B8 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as COSV60143673; called by muse, mutect2, varscan2
- PAPPA | c.1817C>A p.A606D | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV60277268; called by muse, mutect2, varscan2
- PASK | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs777980574, COSV52148375; called by muse, mutect2, varscan2
- PATJ | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57155191; called by muse, mutect2, varscan2
- PCDHB8 | c.2014C>A p.L672M | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV50757222, COSV99177156; called by muse, mutect2, varscan2
- PDK2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV50303244; called by muse, mutect2, varscan2
- PDLIM5 | c.200A>C p.Q67P | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58745026; called by muse, mutect2, varscan2
- PELP1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1378613410, COSV52585657; called by muse, mutect2, varscan2
- PJA1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs200972780, COSV64052572; called by muse, mutect2, varscan2
- PKHD1 | c.8737G>C p.V2913L | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as CM052346, COSV61860002; called by muse, mutect2, varscan2
- POTEE | c.2627T>A p.L876Q | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.206); catalogued as COSV58224072; called by muse, mutect2, varscan2
- PRDM10 | c.3461A>T p.E1154V | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58799239; called by muse, mutect2, varscan2
- PSD | c.1501A>G p.S501G | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV50041715; called by muse, mutect2, varscan2
- PTGIS | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as rs780217825, COSV54834834; called by muse, mutect2, varscan2
- PTPRK | c.3961A>T p.T1321S (on ENST00000368215 / NM_001291984.2; = p.T1322S on NM_002844.4) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as COSV63891033; called by muse, mutect2, varscan2
- PTPRN2 | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs373071385; called by muse, mutect2, varscan2
- RRP12 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.404); catalogued as rs202239906, COSV59664644; called by muse, mutect2, varscan2
- SAAL1 | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55514388; called by muse, mutect2, varscan2
- SCN9A | c.2958C>A p.N986K (on ENST00000303354; = p.N975K on NM_002977.3) | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57599731; called by muse, mutect2, varscan2
- SHCBP1L | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62353305; called by muse, mutect2, varscan2
- SIGLEC1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762267814, COSV52458453; called by muse, mutect2, varscan2
- SLC12A7 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1486695546, COSV53754352; called by muse, mutect2, varscan2
- SLC2A2 | c.65T>A p.F22Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58584425; called by muse, mutect2, varscan2
- SMAD4 | c.1093G>C p.G365R | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100748047, COSV61688839; called by muse, mutect2, varscan2
- SMARCA2 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV56645137; called by muse, mutect2, varscan2
- SMARCA4 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100758817; called by muse, mutect2, varscan2
- TFAP2C | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52370401; called by muse, varscan2
- TGM6 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV52477270; called by muse, mutect2, varscan2
- TMEM215 | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV100713281, COSV61363158; called by muse, mutect2, varscan2
- TRIM26 | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.199); catalogued as COSV68962829; called by muse, mutect2, varscan2
- TRPA1 | c.2566T>G p.C856G | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as COSV51555266; called by muse, mutect2, varscan2
- TRPV5 | c.1122+2T>C p.X374_splice | Splice Site (SNP) | VAF 26/242 reads (11%) | catalogued as COSV54688344, COSV99520735; called by muse, mutect2, varscan2
- TTF2 | c.2651C>A p.P884H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV65632029; called by muse, mutect2, varscan2
- TTN | c.2840C>T p.S947L (on ENST00000591111; = p.S901L on NM_003319.4) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | PolyPhen benign (0.127); catalogued as rs761200839, COSV59880183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT1A7 | c.671dup p.K225Qfs*9 | Frame Shift Ins (INS) | VAF 117/264 reads (44%) | catalogued as rs1476036720; called by mutect2, pindel, varscan2
- UNC13C | c.2578A>G p.K860E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.112); catalogued as COSV52842569; called by muse, mutect2, varscan2
- USH2A | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs551424240, COSV56326210, COSV56400400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDBF2 | c.2726A>T p.N909I | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV65621683; called by muse, mutect2, varscan2
- ZNF354C | c.1496T>C p.M499T | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV59607160; called by muse, mutect2, varscan2
- ZNF416 | c.802A>T p.R268W | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52183369; called by muse, mutect2, varscan2
- ZNF506 | c.345dup p.G116Rfs*3 | Frame Shift Ins (INS) | VAF 112/218 reads (51%) | catalogued as rs1409120867; called by mutect2, varscan2
- ZSCAN29 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as COSV53017648; called by muse, mutect2, varscan2
- ESYT2 | c.644_677del p.K215Rfs*34 (on ENST00000613624; = p.K139Rfs*34 on NM_020728.3) | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel
- IGHG1 | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.12806-1G>A p.X4269_splice | Splice Site (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- ALAD | c.897C>T p.A299= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs370242589, COSV52957974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK1 | c.2817G>A p.P939= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs751319722, COSV55872519; called by muse, mutect2, varscan2
- ARMCX3 | c.306T>A p.R102= | Silent (SNP) | VAF 10/163 reads (6%) | catalogued as COSV100362303; called by muse, mutect2
- ARPP21 | c.1341T>C p.P447= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs1258044082, COSV51791913; called by muse, mutect2, varscan2
- C1QL2 | c.807C>T p.H269= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55605948; called by muse, mutect2, varscan2
- CCDC39 | c.1620C>T p.I540= | Silent (SNP) | VAF 77/143 reads (54%) | catalogued as rs776608064, COSV56478380; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD276 | c.1315C>T p.L439= (on ENST00000318443 / NM_001024736.2; = p.L221= on NM_025240.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/51 reads (67%) | catalogued as COSV59202533; called by muse, mutect2, varscan2
- CNGA4 | c.831G>A p.A277= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1218380327, COSV66004983, COSV66005995; called by muse, mutect2, varscan2
- COL6A3 | c.3546G>A p.P1182= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1220603234, COSV55079386; called by muse, mutect2, varscan2
- CTAGE6 | c.753C>A p.S251= | Silent (SNP) | VAF 141/451 reads (31%) | catalogued as COSV101417865; called by muse, mutect2, varscan2
- DGKG | c.2145G>A p.E715= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53961438; called by muse, mutect2
- DHPS | c.117T>C p.G39= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99269656; called by muse, mutect2, varscan2
- DISP3 | c.1122C>T p.H374= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs761876206, COSV99609308; called by muse, mutect2, varscan2
- DSCAM | c.2400G>A p.T800= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs371668588; called by muse, mutect2, varscan2
- EPB41L4A | c.252C>A p.I84= | Silent (SNP) | VAF 87/160 reads (54%) | catalogued as rs1357854825, COSV54862141; called by muse, mutect2, varscan2
- FEZF2 | c.1266C>T p.C422= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as rs1232855100, COSV51861878; called by muse, mutect2, varscan2
- FIBCD1 | c.1299C>T p.D433= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as rs371058676; called by muse, mutect2, varscan2
- GIMAP8 | c.987G>T p.L329= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV56229657, COSV56234321; called by muse, mutect2, varscan2
- HCAR2 | c.831T>C p.F277= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as COSV61024187; called by muse, mutect2, varscan2
- HCAR3 | c.831T>C p.F277= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100811667; called by muse, mutect2, varscan2
- HERC2 | c.2955G>A p.R985= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs760079208, COSV55306812; called by muse, mutect2, varscan2
- HNRNPAB | c.450G>A p.K150= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs772086445, COSV57422829; called by muse, mutect2, varscan2
- KHDC1 | c.462G>T p.L154= (on ENST00000370384 / NM_001251874.2; = p.L81= on NM_030568.5) | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV57614034; called by muse, mutect2, varscan2
- KSR2 | c.1635C>A p.P545= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV56665448; called by muse, mutect2, varscan2
- LRRC52 | c.738C>A p.I246= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1373604234, COSV54231193; called by muse, mutect2, varscan2
- MAPKAPK3 | c.70T>C p.L24= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV63596794; called by muse, mutect2
- NMUR2 | c.834T>C p.A278= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV54917003; called by muse, mutect2, varscan2
- NRBP1 | c.813G>A p.V271= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV51993047; called by muse, mutect2, varscan2
- PAM | c.1899C>A p.P633= | Silent (SNP) | VAF 83/136 reads (61%) | catalogued as COSV57209225; called by muse, mutect2, varscan2
- PDCL3 | c.378C>G p.L126= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs143673019; called by muse, mutect2, varscan2
- PDZD2 | c.3810G>A p.S1270= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as rs894262957, COSV56850327; called by muse, mutect2, varscan2
- PPP1R3A | c.288G>A p.T96= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs111896635; called by muse, mutect2, varscan2
- PPP6R3 | c.1314T>A p.L438= (on ENST00000393800 / NM_001352375.2; = p.L387= on NM_018312.5) | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55721106; called by muse, mutect2, varscan2
- SHROOM2 | c.414C>T p.S138= | Silent (SNP) | VAF 66/190 reads (35%) | catalogued as rs758504466, COSV101098873; called by muse, varscan2
- SLCO4C1 | c.1173T>G p.T391= | Silent (SNP) | VAF 48/334 reads (14%) | catalogued as COSV60512649, COSV60518563; called by muse, mutect2, varscan2
- SYCP2L | c.708G>A p.A236= | Silent (SNP) | VAF 68/105 reads (65%) | catalogued as rs763660105, COSV51649819; called by muse, mutect2, varscan2
- TFAP2C | c.138C>G p.L46= | Silent (SNP) | VAF 82/172 reads (48%) | catalogued as COSV99571626; called by muse, varscan2
- TVP23B | c.471T>A p.V157= | Silent (SNP) | VAF 98/276 reads (36%) | catalogued as COSV100314608, COSV57059178; called by muse, mutect2, varscan2
- UBAP2 | c.1539T>A p.A513= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV62545106; called by muse, mutect2
- ZEB2 | c.2835T>G p.T945= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as COSV100356451; called by muse, mutect2, varscan2
- ZNF211 | c.300C>A p.S100= (on ENST00000347302 / NM_198855.4; = p.S113= on NM_006385.5) | Silent (SNP) | VAF 86/160 reads (54%) | catalogued as COSV99560361; called by muse, mutect2, varscan2
- ZNF311 | c.144C>T p.N48= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV65852828; called by muse, mutect2, varscan2
- PKD1L2 | n.1315C>T | RNA (SNP) | VAF 7/55 reads (13%) | catalogued as rs758870477; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1598T>G | Intron (SNP) | VAF 89/167 reads (53%) | catalogued as COSV62464529; called by muse, mutect2, varscan2
